Somatic mutation profile of tumor specimen TARGET-10-PARPZI-09A (aliquot TARGET-10-PARPZI-09A-01D) from TARGET case TARGET-10-PARPZI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,316 days).
Specimen TARGET-10-PARPZI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c83b9d79-d816-4bff-9822-422190e87db6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARPZI-10A (Blood Derived Normal), aliquot TARGET-10-PARPZI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/042c1f62-bf18-4899-bfa0-8d01f0948d78

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 4, Silent 4, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY8 | c.3307G>A p.A1103T | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201573600, COSV53895807; called by muse, mutect2, varscan2
- NAALADL2 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.425); catalogued as rs375780484; called by muse, mutect2, varscan2
- RBFOX1 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 34/72 reads (47%) | catalogued as COSV100303712, COSV60948993, COSV60949190; called by muse, mutect2, varscan2
- TTN | c.76724G>A p.R25575H (on ENST00000591111; = p.R18151H on NM_003319.4) | Missense Mutation (SNP) | VAF 17/84 reads (20%) | PolyPhen probably damaging (0.998); catalogued as rs371910831, COSV100621957, COSV59957143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC80 | c.3856G>A p.V1286I | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1012210225, COSV55888880; called by muse, mutect2, varscan2
- AKAP6 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 62/134 reads (46%) | called by muse, mutect2, varscan2
- HDAC9 | c.1535del p.D512Afs*34 | Frame Shift Del (DEL) | VAF 53/149 reads (36%) | called by mutect2, pindel, varscan2
- IKZF1 | c.998dup p.P334Afs*155 | Frame Shift Ins (INS) | VAF 26/85 reads (31%) | called by mutect2, pindel, varscan2
- NALCN | c.1415C>A p.S472* | Nonsense Mutation (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- NEGR1 | c.161_163delinsG p.D54Gfs*5 | Frame Shift Del (DEL) | VAF 37/79 reads (47%) | called by pindel, varscan2*
- COL6A5 | c.3015C>T p.D1005= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs541531354, COSV55194193; called by muse, mutect2, varscan2
- OBSL1 | c.3603C>T p.G1201= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs751546906, COSV54709582; called by muse, mutect2, varscan2
- SHANK1 | c.1248C>T p.Y416= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs777634297; called by muse, varscan2
- ZNF839 | c.2301T>G p.S767= (on ENST00000558850 / NM_001267827.1; = p.S883= on NM_018335.5) | Silent (SNP) | VAF 39/88 reads (44%) | called by muse, mutect2, varscan2
